TCGA case TCGA-13-1483 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/611600a6-43ec-4029-9682-cd6d6a3312ec

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 895 days (2.5 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 61.2 years (22,342 days); Year of diagnosis: 2000; Method of diagnosis: Fine Needle Aspiration; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 176 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 176 days; Number of cycles: 6; Treatment dose: 174 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 219 days; Days to treatment end: 239 days; Number of cycles: 2; Treatment dose: 75 mg/m2; Route of administration: Intraperitoneal.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 62.0 years (22,639 days); Days to diagnosis: 297 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 297 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 297 days; Evidence of recurrence type: Positive Biomarker(s).
- Days to follow up: 895 days (2.5 years); Disease response: With Tumor.
- Karnofsky performance status: 60; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-1483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 1.4; Shortest dimension: 0.4.
  Slide TCGA-13-1483-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 40; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 50.
  Slide TCGA-13-1483-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 45; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 50.
- Sample TCGA-13-1483-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Fine needle aspiration biopsy.
- Drug treatment 1, Route of administrations: Route of administration: IP.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Paciltaxel.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 895 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 895 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 297 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-1483-01A-01D-0472-01): tumor purity 0.77, ploidy 1.93, whole-genome doublings 0.
